TCGA case TCGA-60-2710 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Roswell Park. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b28e3be1-9843-4204-b999-b3e2a909c7bd

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 67.5 years (24,669 days); Year of diagnosis: 2005; AJCC staging edition: 6th; AJCC pathologic T: T1; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: Yes; Days to last follow up: 2,024 days (5.5 years); Sites of involvement: Peripheral Lung.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Neoadjuvant; Days to treatment start: 15 days; Days to treatment end: 57 days; Number of cycles: 3; Treatment dose: 225 mg/m2; Prescribed dose: 75; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pemetrexed; Treatment intent type: Neoadjuvant; Days to treatment start: 15 days; Days to treatment end: 57 days; Number of cycles: 3; Treatment dose: 1,500 mg/m2; Prescribed dose: 500; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Days to treatment start: 148 days; Days to treatment end: 169 days; Number of cycles: 1; Treatment dose: 75 mg; Prescribed dose: 75; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pemetrexed Disodium; Treatment intent type: Adjuvant; Days to treatment start: 148 days; Days to treatment end: 155 days; Number of cycles: 1; Treatment dose: 500 mg/m2; Prescribed dose: 500; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (4 entries)
- Days to follow up: 1,686 days (4.6 years); Disease response: Tumor Free.
- Days to follow up: 1,714 days (4.7 years); Disease response: Tumor Free.
- Days to follow up: 2,024 days (5.5 years); Disease response: Tumor Free.
- Karnofsky performance status: 80; ECOG performance status: 1; Timepoint: Post Adjuvant Therapy.

Other clinical attributes
- DLCO (% of predicted): 61; FEV1/FVC before bronchodilator (%): 67; FEV1 before bronchodilator (% of reference): 61.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 63; Tobacco smoking onset year: 1963; Tobacco smoking quit year: 2005.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-60-2710-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.5; Intermediate dimension: 0.6; Shortest dimension: 0.5.
  Slide TCGA-60-2710-01A-01-TS1: Section location: Top; Percent tumor cells: 82; Percent tumor nuclei: 85; Percent normal cells: 3; Percent necrosis: 5; Percent stromal cells: 10.
  Slide TCGA-60-2710-01A-01-BS1: Section location: Bottom; Percent tumor cells: 76; Percent tumor nuclei: 90; Percent normal cells: 7; Percent necrosis: 7; Percent stromal cells: 10.
- Sample TCGA-60-2710-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-60-2710-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 2.1; Intermediate dimension: 1.1; Shortest dimension: 1.1.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: Yes; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Tobacco smoking history indicator: 4; Anatomic organ subdivision: L-Upper; Location lung parenchyma: Peripheral Lung; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes.
- Drug treatment 1: Regimen number: 2.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 1; Pharmaceutical therapy drug name: premetrexed; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: neo-adjuvant.
- Drug treatment 4: Regimen number: 2; Pharmaceutical therapy drug name: alimta.
- Follow-up form 1: Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free.
- Follow-up form 2: Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; Performance status timing: Post-Adjuvant Therapy.

GDC annotations on this case (curator notes; quoted as recorded):
- Neoadjuvant therapy: Subject Positive for Neo-Adjuvant Therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,024 days; disease-specific survival: no event (censored), 2,024 days; disease-free interval: no event (censored), 2,024 days; progression-free interval: no event (censored), 2,024 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-60-2710-01A-01D-1969-01): tumor purity 0.65, ploidy 1.96, whole-genome doublings 0.
